Gene-level copy-number profile of tumor specimen TCGA-CM-6169-01A from TCGA case TCGA-CM-6169, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.3 years (24,564 days).
Specimen TCGA-CM-6169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e174cea5-8f30-4631-aeb8-51639d26428a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-6169-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c826e5f-fb51-4ba7-8f85-64c5d3ada913

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,795; copy number 2: 51,092; copy number 3: 2,194; copy number 4: 1,710; copy number 5: 1; copy number 6: 1,023.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-6169-01A-11D-1649-01): tumor purity 0.68, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,380,476–6,721,960, 4 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1.
- chr20:14,522,081–14,523,314, 1 gene: AL121582.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,024 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,525,176–35,525,763, 1 gene, copy number 5: LSM12P1.
- chr20:22,960,534–64,313,132, 1,023 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,795. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
